Somatic mutation profile of tumor specimen MMRF_1511_1_BM_CD138pos (aliquot MMRF_1511_1_BM_CD138pos_T1_KBS5U_L02996) from MMRF case MMRF_1511, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.7 years (28,386 days).
Specimen MMRF_1511_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f65f098-06b5-41b5-a413-dfbb053389ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1511_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1511_1_PB_Whole_C3_KBS5U_L03004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/618a4257-7631-493f-b953-fe4ed34d2aa4

The open-access MAF lists 91 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 23, Silent 15, Intron 6, 5'UTR 5, 5'Flank 5, Frame Shift Del 2, 3'Flank 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs776995986, COSV99383231; called by muse, mutect2, varscan2
- C9orf116 | c.322G>A p.V108M (on ENST00000429260 / NM_001048265.2; = p.S92= on NM_144654.3) | Missense Mutation (SNP) | VAF 85/359 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759037219; called by muse, mutect2, varscan2
- CAMKMT | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.225); catalogued as rs202168145, COSV65923867; called by muse, mutect2
- CAST | c.1537G>A p.D513N (on ENST00000341926; = p.D596N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs79809612; called by muse, mutect2, varscan2
- CBLN2 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV54053007; called by muse, mutect2
- DPYSL4 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184776028; called by muse, mutect2
- FYB1 | c.1972G>A p.D658N (on ENST00000351578 / NM_199335.5; = p.D704N on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV99080305; called by muse, mutect2, varscan2
- H1-4 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104388637; called by muse, mutect2, varscan2
- IGHV3-13 | c.285C>G p.N95K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.47); catalogued as rs782157308; called by muse, mutect2
- LOXL3 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as COSV51208029; called by muse, mutect2, varscan2
- MTHFSD | c.427G>A p.A143T (on ENST00000360900 / NM_001159377.2; = p.A142T on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954477348, COSV100530398; called by muse, mutect2, varscan2
- MUC4 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.22); catalogued as rs1328646366; called by muse, mutect2, varscan2
- RABEP2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62868313; called by muse, mutect2
- RPGRIP1L | c.726A>T p.E242D | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); catalogued as CD110633; called by muse, mutect2, varscan2
- SCP2 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs765103479; called by muse, mutect2, varscan2
- ACTG1 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANGPTL6 | c.1118A>T p.Y373F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD16 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C3 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CTRL | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMSY | c.1715_1746del p.M572Kfs*68 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | called by mutect2, pindel
- FLI1 | c.4_11del p.D2Yfs*2 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, varscan2
- IGKV2-28 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- INSRR | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDA3 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLXNA2 | c.5152G>T p.D1718Y | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLXND1 | c.4816G>T p.V1606F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- RAB6B | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL3 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SERINC4 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SLC15A3 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VWA5B2 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WRNIP1 | c.1361G>T p.R454M | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZNF536 | c.3541G>T p.E1181* | Nonsense Mutation (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- AKAP3 | c.2481T>C p.Y827= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3183G>A p.S1061= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1562381590; called by muse, mutect2, varscan2
- CCDC18 | c.735C>T p.A245= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs777667910; called by muse, mutect2, varscan2
- CHRNG | c.873G>A p.V291= | Silent (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.357A>C p.I119= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs139383686; called by muse, mutect2, varscan2
- ITGA6 | c.753T>G p.P251= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- JAK2 | c.408A>T p.I136= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2223G>A p.R741= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- PACSIN3 | c.1017C>A p.P339= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100096329; called by muse, mutect2
- PDCD11 | c.2710T>C p.L904= | Silent (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- SETX | c.1512T>A p.S504= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- SLF2 | c.1656T>C p.P552= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2
- TAZ | c.255C>T p.R85= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1557191585; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3234A>G p.T1078= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- WRNIP1 | c.1360A>C p.R454= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- AL353572.2 | n.579C>A | RNA (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- BLOC1S6 | chr15:45587305 A>G | 5'Flank (SNP) | VAF 25/53 reads (47%) | called by mutect2, varscan2
- C18orf54 | c.*332T>C | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CALHM5 | c.*5230T>C | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- CCDC34 | c.606+931C>T | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- CEP170B | c.*68G>A | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as rs921275565; called by muse, mutect2
- COL4A2 | c.*134C>A | 3'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- DDX18 | c.*307A>G | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*656G>A | 3'UTR (SNP) | VAF 57/161 reads (35%) | catalogued as rs1337317809; called by muse, mutect2, varscan2
- ELN | c.1415-78G>A | Intron (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37734963 A>G | 5'Flank (SNP) | VAF 22/41 reads (54%) | catalogued as rs894327963; called by muse, mutect2, varscan2
- FAM133A | c.*1820C>A | 3'UTR (SNP) | VAF 32/37 reads (86%) | called by muse, mutect2, varscan2
- FBXO46 | c.*387C>T | 3'UTR (SNP) | VAF 63/184 reads (34%) | called by muse, mutect2, varscan2
- FGFR2 | c.939+1224T>C | Intron (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- FZD10 | c.-246G>A | 5'UTR (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- GABRG1 | c.*1918C>T | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- GON7 | c.-16A>C | 5'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- GPR132 | c.-688G>A | 5'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- LINC00632 | n.104+2644C>A | Intron (SNP) | VAF 99/122 reads (81%) | called by muse, mutect2, varscan2
- LPP | c.1240+2324A>C | Intron (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- MEGF9 | c.*2350T>A | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- MLLT3 | c.*1603C>T | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- MRPS25 | c.-25G>A | 5'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1278+72G>A | Intron (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2120A>T | 3'UTR (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- NFASC | c.*5727T>A | 3'UTR (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- NFATC3 | c.*854C>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1614G>A | 3'UTR (SNP) | VAF 32/106 reads (30%) | catalogued as COSV100850134; called by muse, mutect2, varscan2
- PACSIN1 | c.*341G>A | 3'UTR (SNP) | VAF 8/240 reads (3%) | catalogued as rs1186734097; called by muse, mutect2
- RPL31 | c.*539G>C | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- SEC24A | c.*20T>C | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SEC61A1 | chr3:128051962 T>C | 5'Flank (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- SLC25A21 | chr14:37173086 A>C | 5'Flank (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- SLC6A12 | c.*387C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | catalogued as rs760980308; called by muse, mutect2, varscan2
- SLC8A1 | chr2:40113659 A>G | 3'Flank (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*4920del | 3'UTR (DEL) | VAF 13/29 reads (45%) | catalogued as rs959901712; called by mutect2, varscan2
- SPTA1 | c.-153T>A | 5'UTR (SNP) | VAF 88/191 reads (46%) | called by muse, mutect2, varscan2
- TEAD1 | c.*7037C>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | catalogued as rs935898610; called by muse, mutect2, varscan2
- TMEM42 | c.*206T>C | 3'UTR (SNP) | VAF 5/57 reads (9%) | catalogued as rs1218088033; called by muse, mutect2
- TRIM65 | c.*210A>G | 3'UTR (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- XRCC4 | chr5:83077515 C>T | 5'Flank (SNP) | VAF 32/77 reads (42%) | catalogued as rs549934333, COSV56539731; called by muse, mutect2, varscan2
